Somatic mutation profile of tumor specimen ALCH-B02A-TTP1-A (aliquot ALCH-B02A-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B02A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 77.0 years (28,106 days).
Specimen ALCH-B02A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9d6028b-d107-4949-b198-02d8fd8f482d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B02A-NB1-A (Blood Derived Normal), aliquot ALCH-B02A-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92fef566-aec0-4867-94ca-1c8f74376481

The open-access MAF lists 239 somatic variants for this specimen: 166 protein-altering or splice-affecting, 39 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 39, Intron 19, Nonsense Mutation 10, Splice Site 8, Frame Shift Del 8, 3'UTR 4, RNA 4, Splice Region 3, 5'UTR 3, 5'Flank 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 60/283 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs104894226, CM053285, COSV54237021, COSV54237051; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 86/349 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ADAM8 | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as rs751783061; called by muse, mutect2, varscan2
- AGO1 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.795); catalogued as COSV64594995; called by muse, mutect2, varscan2
- AP002512.3 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs142752109; called by muse, mutect2, varscan2
- ARPP21 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.075); catalogued as COSV99490727; called by muse, mutect2, varscan2
- CCDC168 | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as rs368769691; called by muse, mutect2, varscan2
- CFAP46 | c.5704C>A p.L1902M | Missense Mutation (SNP) | VAF 134/543 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV99584800; called by muse, mutect2, varscan2
- CHRM2 | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 169/821 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.604); catalogued as COSV100281916; called by muse, mutect2, varscan2
- COL21A1 | c.1266G>T p.E422D | Missense Mutation (SNP) | VAF 72/468 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as COSV55177797; called by muse, mutect2, varscan2
- CRPPA | c.1055A>G p.Q352R (on ENST00000407010 / NM_001368197.1; = p.Q302R on NM_001101417.4) | Missense Mutation (SNP) | VAF 112/373 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs759200865; called by muse, mutect2, varscan2
- DCC | c.4267G>A p.D1423N | Missense Mutation (SNP) | VAF 72/555 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1222539911; called by muse, mutect2, varscan2
- DEFB110 | c.96C>A p.C32* | Nonsense Mutation (SNP) | VAF 64/289 reads (22%) | catalogued as COSV67018487; called by muse, varscan2
- DHX33 | c.1393C>G p.P465A | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV56580489; called by muse, varscan2
- DIO2 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs891768875; called by muse, mutect2, varscan2
- DSG4 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 79/390 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57390289; called by muse, mutect2, varscan2
- FAM135B | c.1646C>A p.P549Q | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV99425000; called by muse, mutect2, varscan2
- FNTB | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV55761989; called by muse, mutect2, varscan2
- GBA3 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1432030049; called by muse, mutect2, varscan2
- GPATCH1 | c.2765G>A p.R922Q | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs746378383; called by muse, mutect2, varscan2
- GRIN2B | c.1556G>T p.R519L | Missense Mutation (SNP) | VAF 196/951 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV74205414; called by muse, mutect2, varscan2
- HRG | c.1570C>A p.P524T | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV51648290; called by muse, mutect2
- INPP5B | c.589del p.A197Rfs*18 | Frame Shift Del (DEL) | VAF 40/212 reads (19%) | catalogued as rs756926593; called by mutect2, pindel, varscan2
- IRAK2 | c.1231G>T p.G411C | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56535798; called by muse, mutect2, varscan2
- KCNK10 | c.1154G>C p.R385P | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV56640205; called by muse, mutect2, varscan2
- KCNT2 | c.688T>C p.F230L | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as rs1230132904, COSV54099758; called by muse, mutect2
- MIR9-1HG | n.322G>T | Splice Region (SNP) | VAF 57/173 reads (33%) | catalogued as rs1217513858, COSV59483825; called by muse, mutect2, varscan2
- MLLT10 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 70/361 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.019); catalogued as COSV100308564, COSV56990485; called by muse, mutect2, varscan2
- MROH2B | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 38/352 reads (11%) | catalogued as COSV68181026; called by muse, mutect2, varscan2
- MYH15 | c.2494G>C p.A832P | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs914915512; called by muse, mutect2, varscan2
- NF1 | c.3198-2A>C p.X1066_splice | Splice Site (SNP) | VAF 30/122 reads (25%) | catalogued as CS072242, CS087440, CS1212634, COSV62191779, COSV62219542, COSV99049908; called by mutect2, varscan2
- NPAS4 | c.331G>T p.D111Y | Missense Mutation (SNP) | VAF 95/442 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100215285; called by muse, mutect2, varscan2
- NRG3 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 85/506 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs776495833, COSV64555908; called by muse, mutect2, varscan2
- NUP210L | c.3332A>T p.Q1111L | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV55154784; called by muse, mutect2, varscan2
- OR2W1 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs747825657; called by muse, varscan2
- OR6K2 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 84/548 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62743115; called by muse, mutect2, varscan2
- OR9G4 | c.858C>G p.N286K | Missense Mutation (SNP) | VAF 108/469 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100265026; called by muse, mutect2, varscan2
- PCDH11X | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100016239; called by muse, mutect2, varscan2
- PCDHA6 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 128/606 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.289); catalogued as rs1190991665; called by muse, mutect2, varscan2
- PCDHB8 | c.2085G>T p.L695F | Missense Mutation (SNP) | VAF 121/664 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV50754637, COSV99177476; called by muse, mutect2, varscan2
- PCDHGB4 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 28/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773579820, COSV53992639; called by muse, mutect2
- PRAMEF27 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.742); catalogued as rs1408470331; called by mutect2, varscan2
- PRSS36 | c.1166C>A p.P389Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as COSV51638582; called by muse, mutect2, varscan2
- REC114 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.181); catalogued as rs372790389; called by muse, mutect2, varscan2
- RLIM | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60326715; called by muse, varscan2
- ROBO4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs776913148, COSV60627284, COSV60627987; called by muse, mutect2, varscan2
- RYR2 | c.8315G>A p.R2772H | Missense Mutation (SNP) | VAF 118/295 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs922927449, COSV63670759; called by muse, mutect2, varscan2
- RYR2 | c.10966G>T p.E3656* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | catalogued as COSV63708272; called by muse, mutect2
- SETDB1 | c.1769G>T p.R590M | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV104376692; called by muse, mutect2, varscan2
- SNAPC4 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.101); catalogued as rs780415920, COSV53733265; called by muse, mutect2, varscan2
- ST18 | c.362G>T p.C121F | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV52484760; called by muse, varscan2
- STAM | c.473C>G p.A158G | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as rs1554827003; called by muse, varscan2
- SUZ12 | c.917G>T p.R306M | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100496775; called by muse, mutect2, varscan2
- THBS2 | c.3415C>A p.P1139T | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.758); catalogued as rs764000550; called by muse, mutect2, varscan2
- TMEM131 | c.5331G>A p.W1777* | Nonsense Mutation (SNP) | VAF 122/455 reads (27%) | catalogued as COSV51774877, COSV51776064; called by muse, mutect2, varscan2
- TNRC18 | c.5422G>T p.E1808* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | catalogued as COSV68169291; called by muse, mutect2
- TPH1 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 108/479 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51457769; called by muse, mutect2, varscan2
- TTN | c.65404C>G p.R21802G (on ENST00000591111; = p.R14378G on NM_003319.4) | Missense Mutation (SNP) | VAF 26/115 reads (23%) | PolyPhen benign (0.059); catalogued as rs765987438; called by muse, mutect2, varscan2
- ZNF85 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 81/425 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs201139670; called by muse, mutect2, varscan2
- ACSM4 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 346/777 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- ADAM18 | c.488A>G p.K163R | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS15 | c.996G>A p.M332I | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADCY2 | c.43C>A p.R15S | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRE2 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 66/371 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- AMER3 | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- ARHGAP9 | c.535-6T>C | Splice Region (SNP) | VAF 92/346 reads (27%) | called by muse, mutect2, varscan2
- ATP13A2 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 181/709 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ATXN1 | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 79/421 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- BICC1 | c.1379C>G p.P460R | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CACNA1H | c.594C>G p.I198M | Missense Mutation (SNP) | VAF 59/330 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1I | c.5527C>T p.H1843Y | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- CAND1 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CCDC178 | c.1409+1G>T p.X470_splice | Splice Site (SNP) | VAF 24/135 reads (18%) | called by muse, varscan2
- CD226 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CDC123 | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 68/315 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- CENPE | c.3127A>T p.R1043W | Missense Mutation (SNP) | VAF 114/426 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLTC | c.4411T>G p.F1471V | Missense Mutation (SNP) | VAF 127/344 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CNGA2 | c.1018del p.E340Rfs*6 | Frame Shift Del (DEL) | VAF 64/163 reads (39%) | called by mutect2, pindel, varscan2
- COL4A4 | c.3013G>T p.G1005* | Nonsense Mutation (SNP) | VAF 85/558 reads (15%) | called by muse, mutect2, varscan2
- DAZL | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated, low confidence (0.34); called by muse, mutect2, varscan2
- DAZL | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated, low confidence (0.44); called by muse, mutect2, varscan2
- DKK1 | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ELMOD3 | c.739-4C>G | Splice Region (SNP) | VAF 45/387 reads (12%) | called by muse, mutect2, varscan2
- ELOVL1 | c.224del p.Y75Sfs*7 | Frame Shift Del (DEL) | VAF 24/140 reads (17%) | called by mutect2, pindel, varscan2
- EMC1 | c.1719G>T p.M573I | Missense Mutation (SNP) | VAF 105/549 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMILIN2 | c.2037C>A p.S679R | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EN1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FLNC | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 100/562 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FLT4 | c.1592T>G p.M531R | Missense Mutation (SNP) | VAF 89/734 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- FOXP3 | c.696T>G p.C232W | Missense Mutation (SNP) | VAF 196/435 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- FXR1 | c.492A>T p.E164D | Missense Mutation (SNP) | VAF 55/466 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- GABRA1 | c.579A>T p.E193D | Missense Mutation (SNP) | VAF 51/448 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GABRA6 | c.1171C>A p.L391I | Missense Mutation (SNP) | VAF 38/332 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRAMD1A | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- HAUS3 | c.1770A>T p.L590F | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HCN1 | c.2316G>T p.Q772H | Missense Mutation (SNP) | VAF 67/418 reads (16%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HOOK3 | c.1738+1G>T p.X580_splice | Splice Site (SNP) | VAF 44/250 reads (18%) | called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 32/629 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- IGKV1D-17 | c.11G>T p.R4M | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.173); called by muse, varscan2
- JAK2 | c.3313_3320del p.C1105Qfs*2 | Frame Shift Del (DEL) | VAF 22/205 reads (11%) | called by mutect2, pindel, varscan2
- KCNK18 | c.742G>T p.E248* | Nonsense Mutation (SNP) | VAF 112/447 reads (25%) | called by muse, mutect2, varscan2
- KIR3DL1 | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KLF14 | c.250C>A p.L84M | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- KNOP1 | c.1331T>G p.F444C | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRTAP21-2 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- LAMA1 | c.317G>T p.W106L | Missense Mutation (SNP) | VAF 128/608 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LBP | c.1325-2A>T p.X442_splice | Splice Site (SNP) | VAF 64/329 reads (19%) | called by muse, mutect2, varscan2
- LRP1B | c.7277G>T p.R2426I | Missense Mutation (SNP) | VAF 63/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRP1B | c.4048T>A p.Y1350N | Missense Mutation (SNP) | VAF 101/450 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K11 | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- MED17 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 66/331 reads (20%) | called by muse, mutect2, varscan2
- MS4A7 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 59/362 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by mutect2, varscan2
- MUC16 | c.41010+1G>T p.X13670_splice | Splice Site (SNP) | VAF 53/185 reads (29%) | called by muse, mutect2, varscan2
- MYLK | c.476G>C p.C159S | Missense Mutation (SNP) | VAF 122/579 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NEDD4 | c.3459-1G>T p.X1153_splice (on ENST00000508342 / NM_001284338.1; = p.X734_splice on NM_006154.4) | Splice Site (SNP) | VAF 60/238 reads (25%) | called by muse, mutect2, varscan2
- NEGR1 | c.424T>A p.Y142N | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NELL1 | c.398G>T p.G133V | Missense Mutation (SNP) | VAF 17/353 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- NES | c.4237G>T p.A1413S | Missense Mutation (SNP) | VAF 74/507 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- NOTCH2 | c.5500T>G p.L1834V | Missense Mutation (SNP) | VAF 110/627 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- NOTCH3 | c.3124G>T p.E1042* | Nonsense Mutation (SNP) | VAF 51/353 reads (14%) | called by muse, mutect2, varscan2
- NR5A2 | c.900C>A p.S300R (on ENST00000367362 / NM_205860.3; = p.S254R on NM_003822.5) | Missense Mutation (SNP) | VAF 52/864 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- NUP210L | c.3331C>T p.Q1111* | Nonsense Mutation (SNP) | VAF 89/291 reads (31%) | called by muse, mutect2, varscan2
- NUTM2G | c.1559C>G p.A520G | Missense Mutation (SNP) | VAF 59/364 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.11044C>A p.Q3682K | Missense Mutation (SNP) | VAF 154/359 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- OR11L1 | c.511C>A p.R171S | Missense Mutation (SNP) | VAF 92/541 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR4B1 | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PCDH17 | c.3071C>G p.A1024G | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PCDHB1 | c.2027A>G p.D676G | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCDHB16 | c.2226del p.T744Pfs*12 | Frame Shift Del (DEL) | VAF 60/556 reads (11%) | called by mutect2, pindel*
- PCOLCE2 | c.865G>T p.G289C | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.125); called by muse, mutect2
- PEG10 | c.568A>G p.M190V (on ENST00000482108 / NM_001040152.2; = p.M224V on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/505 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2
- PIWIL2 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 39/372 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PLB1 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POM121L2 | c.2362C>A p.Q788K | Missense Mutation (SNP) | VAF 117/572 reads (20%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- POU3F3 | c.1420C>A p.P474T | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PRAMEF12 | c.287+1G>T p.X96_splice | Splice Site (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- PRAMEF15 | c.294-2A>G p.X98_splice | Splice Site (SNP) | VAF 106/536 reads (20%) | called by muse, mutect2, varscan2
- PTPRT | c.3041C>A p.T1014N | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ROCK1 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.043); called by muse, mutect2
- RPS6KC1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 26/474 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- RTCB | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SAXO1 | c.992G>T p.C331F | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- SHOX2 | c.294C>A p.D98E | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPATA31E1 | c.3626G>T p.R1209M | Missense Mutation (SNP) | VAF 86/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TIGD1 | c.105_114del p.I36Gfs*2 | Frame Shift Del (DEL) | VAF 30/256 reads (12%) | called by mutect2, pindel
- TLR4 | c.664G>T p.A222S (on ENST00000355622 / NM_138554.5; = p.A182S on NM_003266.4) | Missense Mutation (SNP) | VAF 187/453 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- TMEM260 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- TMEM30A | c.595_609del p.L199_G203del | In Frame Del (DEL) | VAF 36/294 reads (12%) | called by mutect2, pindel
- TMPRSS2 | c.1326del p.P444Lfs*12 | Frame Shift Del (DEL) | VAF 55/256 reads (21%) | called by mutect2, pindel, varscan2
- TSC2 | c.572T>G p.L191R | Missense Mutation (SNP) | VAF 66/873 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSSK4 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.102427T>C p.S34143P (on ENST00000591111; = p.S26719P on NM_003319.4) | Missense Mutation (SNP) | VAF 53/248 reads (21%) | PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TTN | c.74431A>C p.T24811P (on ENST00000591111; = p.T17387P on NM_003319.4) | Missense Mutation (SNP) | VAF 35/565 reads (6%) | PolyPhen probably damaging (0.984); called by muse, mutect2
- TTN | c.68767A>G p.K22923E (on ENST00000591111; = p.K15499E on NM_003319.4) | Missense Mutation (SNP) | VAF 33/138 reads (24%) | PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- UPF2 | c.743T>A p.F248Y | Missense Mutation (SNP) | VAF 79/364 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- USP4 | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 84/375 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- UTP20 | c.3488T>C p.F1163S | Missense Mutation (SNP) | VAF 94/481 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- VPS13B | c.4694A>T p.Q1565L | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VPS13C | c.9275A>T p.H3092L (on ENST00000644861 / NM_020821.3; = p.H3049L on NM_017684.5) | Missense Mutation (SNP) | VAF 13/405 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2
- WDFY3 | c.9886G>T p.D3296Y | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF136 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2
- ZNF317 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF626 | c.507del p.K171Nfs*6 | Frame Shift Del (DEL) | VAF 66/375 reads (18%) | called by mutect2, pindel, varscan2
- ZNF804A | c.1456C>G p.Q486E | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF91 | c.2245A>C p.K749Q | Missense Mutation (SNP) | VAF 50/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN25 | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.229); called by muse, mutect2
- AGMO | c.354T>C p.Y118= | Silent (SNP) | VAF 34/228 reads (15%) | called by muse, mutect2, varscan2
- ALPI | c.516C>T p.H172= | Silent (SNP) | VAF 104/460 reads (23%) | catalogued as rs765904572; called by muse, mutect2, varscan2
- AMER3 | c.825T>C p.A275= | Silent (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- ARF3 | c.507C>G p.G169= | Silent (SNP) | VAF 68/321 reads (21%) | called by muse, mutect2, varscan2
- CERT1 | c.696T>C p.H232= (on ENST00000405807 / NM_001130105.1; = p.H104= on NM_005713.3) | Silent (SNP) | VAF 39/300 reads (13%) | catalogued as rs766813712; called by muse, varscan2
- CFAP46 | c.5703C>A p.S1901= | Silent (SNP) | VAF 138/552 reads (25%) | catalogued as COSV99584804; called by muse, mutect2, varscan2
- CLPSL1 | c.267G>T p.L89= | Silent (SNP) | VAF 108/1042 reads (10%) | catalogued as rs561535280; called by muse, mutect2
- COL4A4 | c.3012G>C p.P1004= | Silent (SNP) | VAF 83/553 reads (15%) | called by muse, mutect2, varscan2
- DNAH17 | c.5739C>G p.A1913= | Silent (SNP) | VAF 21/122 reads (17%) | called by muse, mutect2, varscan2
- E2F1 | c.1104C>T p.P368= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs749886199, COSV99864994; called by muse, mutect2, varscan2
- FAF2 | c.1236G>T p.L412= | Silent (SNP) | VAF 35/379 reads (9%) | called by muse, mutect2
- FAM135B | c.1647A>G p.P549= | Silent (SNP) | VAF 40/213 reads (19%) | catalogued as COSV52744344; called by muse, mutect2, varscan2
- FFAR3 | c.114C>G p.V38= | Silent (SNP) | VAF 164/1404 reads (12%) | called by muse, mutect2, varscan2
- FMNL2 | c.786A>C p.T262= | Silent (SNP) | VAF 93/343 reads (27%) | called by muse, mutect2, varscan2
- HIBCH | c.576T>G p.G192= | Silent (SNP) | VAF 32/718 reads (4%) | called by muse, mutect2
- METTL17 | c.741C>T p.F247= | Silent (SNP) | VAF 199/490 reads (41%) | called by muse, varscan2
- METTL7B | c.636T>C p.L212= | Silent (SNP) | VAF 117/599 reads (20%) | called by muse, mutect2, varscan2
- MS4A7 | c.216C>A p.P72= | Silent (SNP) | VAF 64/390 reads (16%) | called by muse, mutect2, varscan2
- NEURL1 | c.1584G>A p.A528= | Silent (SNP) | VAF 116/510 reads (23%) | catalogued as rs74154555, COSV100583459; called by muse, mutect2, varscan2
- NPAT | c.3384A>G p.L1128= | Silent (SNP) | VAF 12/348 reads (3%) | called by muse, mutect2
- OPRD1 | c.735G>A p.L245= | Silent (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- OR13J1 | c.366C>T p.R122= | Silent (SNP) | VAF 80/276 reads (29%) | called by muse, mutect2, varscan2
- OR4S1 | c.423G>C p.L141= | Silent (SNP) | VAF 52/278 reads (19%) | catalogued as COSV60678869; called by muse, varscan2
- PCDHA4 | c.2190C>T p.G730= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as rs370062696, COSV63543862; called by muse, mutect2
- PFN4 | c.358C>T p.L120= | Silent (SNP) | VAF 39/268 reads (15%) | called by muse, mutect2, varscan2
- PIEZO2 | c.6951A>G p.R2317= | Silent (SNP) | VAF 13/380 reads (3%) | called by muse, mutect2
- PPP2CB | c.300T>C p.L100= | Silent (SNP) | VAF 36/178 reads (20%) | called by mutect2, varscan2
- SATB2 | c.1263C>T p.F421= | Silent (SNP) | VAF 160/787 reads (20%) | catalogued as COSV53480782; called by muse, mutect2, varscan2
- SEZ6L2 | c.2145C>T p.H715= (on ENST00000308713 / NM_001114099.3; = p.H645= on NM_012410.4) | Silent (SNP) | VAF 24/66 reads (36%) | called by muse, varscan2
- SLC37A3 | c.1056A>G p.V352= | Silent (SNP) | VAF 77/465 reads (17%) | called by muse, mutect2, varscan2
- STAB2 | c.3696C>T p.F1232= | Silent (SNP) | VAF 29/124 reads (23%) | called by muse, mutect2, varscan2
- STYXL2 | c.3363G>T p.R1121= | Silent (SNP) | VAF 215/610 reads (35%) | called by muse, mutect2, varscan2
- TDRD6 | c.3042G>A p.Q1014= | Silent (SNP) | VAF 36/153 reads (24%) | called by muse, mutect2, varscan2
- TXNDC5 | c.1233C>T p.H411= | Silent (SNP) | VAF 114/612 reads (19%) | catalogued as rs978766444; called by muse, mutect2, varscan2
- UBR4 | c.3267A>T p.I1089= | Silent (SNP) | VAF 67/243 reads (28%) | called by muse, mutect2, varscan2
- ZIC1 | c.57G>T p.A19= | Silent (SNP) | VAF 76/164 reads (46%) | catalogued as COSV51550355, COSV51557226; called by muse, mutect2, varscan2
- ZNF423 | c.2574C>A p.T858= (on ENST00000563137 / NM_001379286.1; = p.T850= on NM_015069.4) | Silent (SNP) | VAF 21/148 reads (14%) | called by muse, mutect2, varscan2
- ZNF560 | c.912G>A p.Q304= | Silent (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- ZNF837 | c.1443C>A p.G481= | Silent (SNP) | VAF 11/160 reads (7%) | catalogued as rs1266469108; called by muse, mutect2
- AC068587.8 | n.170G>T | RNA (SNP) | VAF 37/486 reads (8%) | catalogued as rs1214591974; called by muse, varscan2
- AC092718.9 | chr16:81157086 C>A | 3'Flank (SNP) | VAF 49/155 reads (32%) | called by muse, mutect2, varscan2
- ADD2 | c.1742-331G>C | Intron (SNP) | VAF 28/372 reads (8%) | called by muse, mutect2
- ANXA10 | c.-22G>T | 5'UTR (SNP) | VAF 91/464 reads (20%) | catalogued as COSV100828968; called by muse, mutect2, varscan2
- BCKDHB | c.*27A>G | 3'UTR (SNP) | VAF 31/528 reads (6%) | called by muse, mutect2
- C2CD6 | c.1581+3579A>G | Intron (SNP) | VAF 44/309 reads (14%) | called by muse, mutect2, varscan2
- CCDC151 | chr19:11435687 G>C | 5'Flank (SNP) | VAF 50/282 reads (18%) | called by muse, mutect2, varscan2
- CCDC154 | c.7+32G>A | Intron (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- CLRN1 | c.*73A>G | 3'UTR (SNP) | VAF 75/387 reads (19%) | catalogued as rs761229375; called by muse, mutect2, varscan2
- CSNK1G1 | c.182-6597A>G | Intron (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- DAGLB | c.1141-11C>G | Intron (SNP) | VAF 60/348 reads (17%) | called by muse, mutect2, varscan2
- DHRS9 | c.-394C>T | 5'UTR (SNP) | VAF 61/397 reads (15%) | called by muse, mutect2, varscan2
- DOCK8 | c.741+308C>G | Intron (SNP) | VAF 31/103 reads (30%) | catalogued as rs1445404308; called by mutect2, varscan2
- FAM227A | c.*3210C>A | 3'UTR (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- HERC2 | c.13273-310C>T | Intron (SNP) | VAF 146/725 reads (20%) | called by muse, mutect2, varscan2
- IL17F | c.34-50T>G | Intron (SNP) | VAF 69/312 reads (22%) | called by muse, mutect2, varscan2
- LDLRAD2 | c.806-18G>A | Intron (SNP) | VAF 70/283 reads (25%) | called by muse, mutect2, varscan2
- LVRN | c.2038-52G>A | Intron (SNP) | VAF 101/544 reads (19%) | called by muse, mutect2, varscan2
- MAGT1 | chrX:77895447 C>A | 5'Flank (SNP) | VAF 93/227 reads (41%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85719C>A | Intron (SNP) | VAF 207/924 reads (22%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92927G>C | Intron (SNP) | VAF 55/292 reads (19%) | catalogued as COSV59034112; called by muse, mutect2, varscan2
- NAMPTP1 | n.1047G>T | RNA (SNP) | VAF 110/476 reads (23%) | called by muse, varscan2
- NAV3 | c.2024-12690G>T | Intron (SNP) | VAF 110/463 reads (24%) | called by muse, mutect2, varscan2
- NXF5 | n.1939A>C | RNA (SNP) | VAF 16/163 reads (10%) | called by muse, mutect2
- OVCH1-AS1 | n.436A>G | RNA (SNP) | VAF 138/434 reads (32%) | catalogued as rs1161873822; called by muse, mutect2, varscan2
- PPP4R3A | c.1266+39A>G | Intron (SNP) | VAF 32/169 reads (19%) | catalogued as rs966858101; called by muse, varscan2
- PRPF31 | c.421-33C>T | Intron (SNP) | VAF 142/471 reads (30%) | catalogued as rs587645965; called by muse, mutect2, varscan2
- PTPN4 | c.2695-23G>T | Intron (SNP) | VAF 42/252 reads (17%) | called by muse, varscan2
- RAD51D | c.-187C>T | 5'UTR (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- SLCO4A1 | chr20:62642326 C>G | 5'Flank (SNP) | VAF 25/168 reads (15%) | called by muse, mutect2, varscan2
- SPTLC1 | c.*138_*171del | 3'UTR (DEL) | VAF 82/402 reads (20%) | called by mutect2, pindel
- TTN | c.10361-4401G>C | Intron (SNP) | VAF 30/212 reads (14%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3553G>T | Intron (SNP) | VAF 22/160 reads (14%) | catalogued as COSV65185047; called by muse, mutect2, varscan2
- ZNF783 | c.802+3554G>T | Intron (SNP) | VAF 22/158 reads (14%) | called by muse, mutect2, varscan2
